Somatic mutation profile of tumor specimen TCGA-CH-5764-01A (aliquot TCGA-CH-5764-01A-21D-1576-08) from TCGA case TCGA-CH-5764, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.4 years (24,257 days).
Specimen TCGA-CH-5764-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1524b823-57f7-4752-9b2c-843a6e472aaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5764-11A (Solid Tissue Normal), aliquot TCGA-CH-5764-11A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b58d9b72-d3e7-41b0-aff8-5a53cca4d0fc

The open-access MAF lists 27 somatic variants for this specimen: 25 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 20, Silent 2, Nonsense Mutation 1, Splice Site 1, Splice Region 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD17B | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 75/312 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61007679; called by muse, mutect2, varscan2
- AGTR1 | c.74A>C p.N25T | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV62557873; called by muse, mutect2, varscan2
- BMP6 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.048); catalogued as COSV51660351; called by muse, mutect2
- BRCA2 | c.4304A>C p.N1435T | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66452206; called by muse, mutect2
- CDH17 | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.459); catalogued as rs201729274, COSV50327363; called by muse, mutect2, varscan2
- CLEC14A | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV60562266, COSV60564682; called by muse, mutect2, varscan2
- CNNM4 | c.1798C>A p.H600N | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV65660589; called by muse, mutect2
- EPS15 | c.2544+2T>C p.X848_splice | Splice Site (SNP) | VAF 43/181 reads (24%) | catalogued as COSV65541661; called by muse, mutect2, varscan2
- FAM83B | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 20/204 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV60921334; called by muse, mutect2
- FRAS1 | c.11162T>A p.L3721Q | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53604108; called by muse, mutect2, varscan2
- LGSN | c.1157A>G p.Y386C | Missense Mutation (SNP) | VAF 143/474 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as rs1274609182, COSV65726899; called by muse, mutect2, varscan2
- LINGO2 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs746922513, COSV58057110; called by muse, mutect2, varscan2
- MGAM | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs537674844, COSV72074462; called by muse, mutect2
- MIIP | c.911T>G p.F304C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV52427466; called by muse, mutect2, varscan2
- PNMA8A | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765826328, COSV58136636; called by muse, mutect2, varscan2
- PRPF38B | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1399130954, COSV64223740; called by muse, mutect2, varscan2
- SIGLEC1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762267814, COSV52458453; called by muse, mutect2
- SPEN | c.4423C>T p.R1475* | Nonsense Mutation (SNP) | VAF 12/201 reads (6%) | catalogued as COSV65360605; called by muse, mutect2
- SPTA1 | c.6368C>A p.T2123K | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63748134; called by muse, mutect2, varscan2
- STAG3 | c.1073A>T p.E358V | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV57928168, COSV57929244; called by muse, mutect2
- TBC1D2 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV59784347, COSV59787120; called by muse, mutect2
- TFAP2D | c.1213A>G p.M405V | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.417); catalogued as COSV50412674; called by muse, mutect2, varscan2
- TNC | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 76/816 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60783642; called by muse, mutect2
- CCDC39 | c.122del p.L41Cfs*15 | Frame Shift Del (DEL) | VAF 30/170 reads (18%) | called by mutect2, pindel, varscan2
- REV1 | c.2346-3del | Splice Region (DEL) | VAF 55/268 reads (21%) | called by mutect2, pindel, varscan2
- BRD8 | c.3201C>T p.G1067= | Silent (SNP) | VAF 15/174 reads (9%) | catalogued as COSV54725792; called by muse, mutect2
- RXYLT1 | c.84C>T p.F28= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs200123669; ClinVar: likely benign; called by mutect2, varscan2
